Gene-level copy-number profile of tumor specimen TCGA-49-4512-01A from TCGA case TCGA-49-4512, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.8 years (25,502 days).
Specimen TCGA-49-4512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ada9c3d8-319f-41e1-9c9a-09aeffc6d68e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4512-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98bd4a20-4c78-4798-8dae-333ddf7a7a30

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 540; copy number 2: 4,425; copy number 3: 2,967; copy number 4: 23,630; copy number 5: 10,841; copy number 6: 6,991; copy number 7: 5,369; copy number 8: 272; copy number 9: 644; copy number 10: 2,540; copy number 11: 145; copy number 12: 1,373; copy number 13: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4512-01A-21D-1854-01): tumor purity 0.32, ploidy 4.56, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,510 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–161,214,723, 812 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:161,399,409–163,468,605, 61 genes, copy number 11 (broad region; genes not listed).
- chr1:167,220,876–168,495,685, 32 genes, copy number 11 (within-gene range 4–11): POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1.
- chr1:170,369,223–170,647,339, 5 genes, copy number 12: HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1.
- chr1:171,248,471–171,285,978, 1 gene, copy number 11 (within-gene range 4–11): FMO1.
- chr1:171,270,954–171,824,959, 19 genes, copy number 11: HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2.
- chr1:174,756,850–175,335,459, 17 genes, copy number 11: BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1.
- chr1:177,351,562–177,920,152, 2 genes, copy number 12 (within-gene range 4–12): LINC01645, AL136114.1.
- chr8:56,776,283–145,066,685, 1,366 genes, copy number 12 (broad region; genes not listed).
- chr12:24,566,964–25,108,334, 15 genes, copy number 10: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2.
- chr12:38,994,803–40,142,876, 15 genes, copy number 11: AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555.
- chr12:40,692,439–42,238,349, 15 genes, copy number 10: CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2.
- chr21:10,328,411–21,543,329, 150 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
